Somatic mutation profile of tumor specimen C3N-04695-03 (aliquot CPT0293870006) from CPTAC case C3N-04695, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.0 years (24,823 days).
Specimen C3N-04695-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b51bf8dd-f2e5-4b8d-8d60-54413f29c4c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04695-31 (Blood Derived Normal), aliquot CPT0293890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04fff6d3-2666-470b-b3f3-953c7e6598a8

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 9, Intron 5, 5'UTR 2, RNA 2, In Frame Del 1, Nonsense Mutation 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANHX | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.248); catalogued as rs1386163786; called by muse, mutect2, varscan2
- C14orf28 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as rs1202601891, COSV100290224; called by muse, varscan2
- C3 | c.2548G>A p.V850I | Missense Mutation (SNP) | VAF 204/567 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.099); catalogued as rs544858538; called by muse, mutect2, varscan2
- CACNA1S | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777962341, COSV62943840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALN1 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.084); catalogued as rs748601544, COSV67960401; called by muse, mutect2, varscan2
- CEP128 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200105295, COSV53672384; called by muse, mutect2, varscan2
- DNAH14 | c.3896G>A p.R1299H (on ENST00000445597; = p.R1709H on NM_001367479.1) | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs143916022; called by muse, mutect2, varscan2
- FAM102B | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV64240258, COSV64241224; called by muse, mutect2, varscan2
- FTMT | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs759353035, COSV58420489; called by muse, mutect2, varscan2
- KLK9 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs1311860048; called by muse, mutect2, varscan2
- LCP1 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753322508; called by muse, mutect2, varscan2
- MLXIPL | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs369598943, COSV57667971; called by muse, mutect2
- NOS1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs766387733, COSV100501325; called by muse, mutect2
- OR4A16 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs144905099, COSV59044107; called by muse, mutect2, varscan2
- PTEN | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 130/259 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100911657; called by muse, mutect2, varscan2
- PUS10 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as rs1203319308; called by muse, mutect2, varscan2
- RFTN1 | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447181563; called by muse, mutect2, varscan2
- RIMBP2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs376169658; called by muse, mutect2, varscan2
- SNF8 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.632); catalogued as rs779528259; called by muse, mutect2, varscan2
- TMEM132D | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 136/483 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs368282993, COSV101396890, COSV70610292; called by muse, mutect2, varscan2
- TMEM132E | c.1037G>A p.R346Q (on ENST00000321639; = p.R436Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs550910621; called by muse, mutect2, varscan2
- TP53BP1 | c.4003G>A p.G1335R | Missense Mutation (SNP) | VAF 27/471 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as rs200761797, COSV55507777; called by muse, mutect2
- TTN | c.24986G>A p.R8329H (on ENST00000591111; = p.R7402H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | PolyPhen benign (0); catalogued as rs144587343; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- UBR4 | c.4181G>A p.R1394H | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs756549939, COSV64385199; called by muse, mutect2, varscan2
- UBXN11 | c.239C>T p.T80M (on ENST00000374221 / NM_183008.2; = p.T47M on NM_145345.2) | Missense Mutation (SNP) | VAF 33/418 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs201705864; called by muse, mutect2
- USP7 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs775166718; called by muse, mutect2, varscan2
- WDFY3 | c.7583G>A p.R2528H | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1334967892, COSV99884739; called by muse, mutect2, varscan2
- ABCA4 | c.5701T>C p.F1901L | Missense Mutation (SNP) | VAF 174/488 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ARHGAP9 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID3C | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 106/217 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IL12RB2 | c.353T>G p.I118S | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- INF2 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 169/534 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MKRN3 | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MYO1B | c.3228G>T p.K1076N (on ENST00000304164; = p.K1018N on NM_012223.5) | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYOD1 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYT1 | c.2396+1G>A p.X799_splice | Splice Site (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- NPFFR2 | c.1127A>T p.K376M | Missense Mutation (SNP) | VAF 105/309 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NUDT7 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OLIG1 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR2M5 | c.42_44del p.L15del | In Frame Del (DEL) | VAF 36/121 reads (30%) | called by pindel, varscan2
- OR7G2 | c.256A>T p.N86Y | Missense Mutation (SNP) | VAF 94/304 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- RYR2 | c.3301T>C p.W1101R | Missense Mutation (SNP) | VAF 120/384 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SEC31A | c.1696A>T p.S566C (on ENST00000355196 / NM_001318120.1; = p.S527C on NM_016211.4) | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TNFRSF10D | c.435C>A p.S145R | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TNS4 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- VPS16 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ANKRD23 | c.690C>T p.I230= | Silent (SNP) | VAF 67/220 reads (30%) | catalogued as rs1464043704; called by muse, mutect2, varscan2
- CGB8 | c.240C>T p.R80= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1045268348; called by mutect2, varscan2
- DNAH1 | c.7926C>A p.L2642= | Silent (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- EIF2S3B | c.39G>A p.P13= | Silent (SNP) | VAF 117/330 reads (35%) | catalogued as rs1479078584, COSV59373643; called by muse, mutect2, varscan2
- GRM8 | c.1857C>T p.R619= | Silent (SNP) | VAF 88/445 reads (20%) | catalogued as COSV58805752, COSV58854595; called by muse, mutect2, varscan2
- MMRN1 | c.3324G>A p.T1108= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs751648461; called by muse, mutect2, varscan2
- MYOD1 | c.507C>A p.A169= | Silent (SNP) | VAF 90/274 reads (33%) | called by muse, mutect2, varscan2
- SELENOT | c.78G>A p.V26= | Silent (SNP) | VAF 72/229 reads (31%) | called by muse, mutect2, varscan2
- TMC8 | c.306C>T p.F102= | Silent (SNP) | VAF 130/355 reads (37%) | catalogued as rs199498761, COSV59209742, COSV59211455; called by muse, mutect2, varscan2
- ACTG1 | c.-419C>T | 5'UTR (SNP) | VAF 35/172 reads (20%) | catalogued as rs781836332, COSV59510586; ClinVar: likely benign; called by muse, mutect2, varscan2
- BMS1P15 | n.490G>A | RNA (SNP) | VAF 30/116 reads (26%) | catalogued as rs759789341; called by muse, mutect2, varscan2
- CYP2C9 | c.169-30G>A | Intron (SNP) | VAF 96/198 reads (48%) | catalogued as rs757562041; called by muse, mutect2, varscan2
- DVL1 | c.-20C>T | 5'UTR (SNP) | VAF 66/182 reads (36%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92961C>A | Intron (SNP) | VAF 35/123 reads (28%) | called by muse, mutect2, varscan2
- OR10AB1P | n.633G>A | RNA (SNP) | VAF 54/199 reads (27%) | catalogued as rs1037765341; called by muse, mutect2, varscan2
- PSD3 | c.1635-3906C>T | Intron (SNP) | VAF 57/154 reads (37%) | catalogued as rs577626339; called by muse, mutect2, varscan2
- SLC28A1 | c.*10A>G | 3'UTR (SNP) | VAF 30/460 reads (7%) | catalogued as rs771349797; called by muse, mutect2
- SLC4A7 | c.3564-2415A>G | Intron (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- TENM3 | c.511+2962G>A | Intron (SNP) | VAF 11/42 reads (26%) | called by mutect2, varscan2
